Somatic mutation profile of tumor specimen C3N-04686-04 (aliquot CPT0293570006) from CPTAC case C3N-04686, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.3 years (21,303 days).
Specimen C3N-04686-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34ff2004-e0dd-4db7-8384-40cec9661c71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04686-31 (Blood Derived Normal), aliquot CPT0293620002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec5c0472-cd0c-4ace-aab2-093a35c09413

The open-access MAF lists 69 somatic variants for this specimen: 42 protein-altering or splice-affecting, 18 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 18, Intron 5, RNA 3, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 3065/6648 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs139236063, COSV51769031, COSV51808387; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 101/160 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1554825226, COSV64289114, COSV64289498, COSV64301765; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMER3 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 109/281 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs368379439; called by muse, mutect2, varscan2
- AP1M1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 58/307 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs369323152; called by muse, mutect2, varscan2
- CALN1 | c.433C>T p.R145* (on ENST00000329008 / NM_001017440.3; = p.R187* on NM_031468.4) | Nonsense Mutation (SNP) | VAF 47/195 reads (24%) | catalogued as rs768173048; called by muse, mutect2, varscan2
- CDH12 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as rs371189490; called by muse, mutect2, varscan2
- CDH18 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 93/265 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1031926484, COSV56923155; called by muse, mutect2, varscan2
- CELF4 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 93/230 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.013); catalogued as COSV104404283; called by muse, mutect2, varscan2
- CFAP43 | c.1514C>T p.S505F | Missense Mutation (SNP) | VAF 59/95 reads (62%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1348135398; called by muse, mutect2, varscan2
- CR1L | c.651G>T p.W217C | Missense Mutation (SNP) | VAF 210/567 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54327175; called by muse, mutect2, varscan2
- CSF2 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 243/587 reads (41%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.608); catalogued as rs200145269; called by muse, mutect2, varscan2
- DDX25 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 79/221 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs760155949, COSV54993489, COSV54993798; called by muse, mutect2, varscan2
- DNAH8 | c.3959G>A p.R1320H | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs375507271; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOK6 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); catalogued as rs150709681; called by muse, mutect2, varscan2
- DUOX1 | c.2165G>A p.R722Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1377116710; called by muse, mutect2, varscan2
- EGFR | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 911/9130 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as COSV51785554, COSV51829933; called by muse, mutect2
- GCGR | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 175/398 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs567794794, COSV101273228; called by muse, mutect2, varscan2
- HERC2 | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.976); catalogued as rs751715258, COSV55341140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITGB5 | c.1263G>A p.T421= | Splice Region (SNP) | VAF 26/87 reads (30%) | catalogued as rs778010440, COSV56150396; called by muse, mutect2, varscan2
- KRTAP4-6 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 224/577 reads (39%) | SIFT tolerated (0.13); catalogued as rs763253803, COSV61980902; called by muse, varscan2
- LIG3 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as rs758823264, COSV52006316; called by muse, mutect2, varscan2
- LTBP3 | c.2863G>T p.E955* | Nonsense Mutation (SNP) | VAF 58/155 reads (37%) | catalogued as COSV54211792; called by muse, mutect2, varscan2
- MYLK3 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.023); catalogued as rs528981118; called by muse, mutect2, varscan2
- PCDHGB4 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 280/688 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.411); catalogued as rs369319162; called by muse, mutect2, varscan2
- PTCHD4 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 138/333 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs191919500, COSV100260253; called by muse, mutect2, varscan2
- SERPINA6 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 142/432 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs149012523; called by muse, mutect2, varscan2
- SLC35G6 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs530873703, COSV59497456; called by muse, mutect2, varscan2
- SYNJ2 | c.3269G>A p.R1090H | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.77); catalogued as rs141300011; called by muse, mutect2, varscan2
- TRAV17 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as rs377652426; called by muse, mutect2, varscan2
- TRIO | c.5107C>T p.R1703C | Missense Mutation (SNP) | VAF 162/412 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs143962916, COSV60085114; called by muse, mutect2, varscan2
- TRPM6 | c.5967G>C p.R1989S | Missense Mutation (SNP) | VAF 111/277 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.895); catalogued as COSV62522031; called by muse, mutect2, varscan2
- TTN | c.52915G>A p.E17639K (on ENST00000591111; = p.E10215K on NM_003319.4) | Missense Mutation (SNP) | VAF 180/405 reads (44%) | PolyPhen benign (0.049); catalogued as rs566966765; called by muse, mutect2, varscan2
- CCND1 | c.830A>T p.E277V | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- DSP | c.5895G>T p.K1965N | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2
- FANCC | c.1373G>A p.R458K | Missense Mutation (SNP) | VAF 194/466 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FLG | c.4565C>A p.T1522N | Missense Mutation (SNP) | VAF 16/510 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- LRRC4C | c.332A>G p.H111R | Missense Mutation (SNP) | VAF 91/258 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.164); called by muse, mutect2
- SLC16A7 | c.1117A>T p.S373C | Missense Mutation (SNP) | VAF 96/243 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STYXL2 | c.251del p.M84Sfs*60 | Frame Shift Del (DEL) | VAF 95/269 reads (35%) | called by mutect2, pindel, varscan2
- SWT1 | c.1105A>G p.I369V | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- TRAJ36 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 16/244 reads (7%) | called by muse, mutect2
- ZNF479 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 81/404 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- AICDA | c.387G>C p.L129= | Silent (SNP) | VAF 28/570 reads (5%) | catalogued as COSV57564082; called by muse, mutect2
- ANO8 | c.2865G>A p.A955= | Silent (SNP) | VAF 52/208 reads (25%) | catalogued as rs763998767; called by muse, mutect2, varscan2
- CD163 | c.3327C>T p.D1109= | Silent (SNP) | VAF 47/112 reads (42%) | catalogued as rs201736696; called by muse, mutect2, varscan2
- DHX57 | c.3975C>T p.S1325= | Silent (SNP) | VAF 109/273 reads (40%) | catalogued as rs1442109674; called by muse, mutect2, varscan2
- DRD5 | c.690G>A p.S230= | Silent (SNP) | VAF 112/272 reads (41%) | catalogued as COSV58577842; called by muse, mutect2, varscan2
- EDAR | c.519C>T p.H173= | Silent (SNP) | VAF 190/500 reads (38%) | catalogued as rs144187827; called by muse, varscan2
- FAM83H | c.2382C>T p.R794= | Silent (SNP) | VAF 142/338 reads (42%) | catalogued as rs782812911; called by muse, mutect2, varscan2
- GABRA3 | c.1266C>A p.P422= | Silent (SNP) | VAF 18/286 reads (6%) | catalogued as rs1177249818, COSV64801354; called by muse, mutect2
- IFT140 | c.3858T>C p.Y1286= | Silent (SNP) | VAF 21/220 reads (10%) | called by muse, mutect2
- LAMB1 | c.4317C>T p.N1439= | Silent (SNP) | VAF 216/735 reads (29%) | catalogued as rs143816350; called by muse, mutect2, varscan2
- LHX5 | c.735C>T p.G245= | Silent (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- OTOP3 | c.1656C>T p.I552= | Silent (SNP) | VAF 106/263 reads (40%) | catalogued as rs773928388, COSV100172741; called by muse, mutect2, varscan2
- PCDHB13 | c.1215G>A p.T405= | Silent (SNP) | VAF 94/241 reads (39%) | catalogued as rs200643533, COSV53401300; called by muse, mutect2, varscan2
- POGZ | c.1719A>G p.P573= | Silent (SNP) | VAF 79/205 reads (39%) | catalogued as rs189465604; called by muse, mutect2, varscan2
- RIPOR3 | c.606C>T p.G202= | Silent (SNP) | VAF 38/104 reads (37%) | catalogued as rs775097185, COSV50385653; called by muse, mutect2, varscan2
- RSPO1 | c.102C>T p.A34= | Silent (SNP) | VAF 155/424 reads (37%) | catalogued as rs746161623, COSV62973808; called by muse, mutect2, varscan2
- SIGLEC11 | c.1290C>T p.H430= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as rs201076601, COSV70221904; called by muse, varscan2
- XIRP2 | c.360G>C p.V120= | Silent (SNP) | VAF 48/131 reads (37%) | catalogued as COSV54726717, COSV99745547; called by muse, mutect2, varscan2
- FAM172BP | n.594C>T | RNA (SNP) | VAF 87/205 reads (42%) | called by muse, mutect2, varscan2
- FAM183BP | n.1039C>T | RNA (SNP) | VAF 138/538 reads (26%) | catalogued as rs1474140319; called by muse, mutect2, varscan2
- FCRL2 | c.884-61G>A | Intron (SNP) | VAF 56/160 reads (35%) | catalogued as rs747814546; called by muse, mutect2, varscan2
- GYS1 | c.*129C>T | 3'UTR (SNP) | VAF 6/11 reads (55%) | catalogued as rs995940133; called by muse, mutect2, varscan2
- KRT77 | c.759-18C>A | Intron (SNP) | VAF 8/170 reads (5%) | called by muse, mutect2
- RDH12 | c.848+50G>T | Intron (SNP) | VAF 35/381 reads (9%) | called by muse, mutect2
- RUFY3 | c.178+18915G>T | Intron (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2, varscan2
- TPRX2P | n.136C>T | RNA (SNP) | VAF 38/106 reads (36%) | catalogued as rs936356500; called by mutect2, varscan2
- UBAP2L | c.3168+420C>T | Intron (SNP) | VAF 102/302 reads (34%) | called by muse, mutect2, varscan2
